Somatic mutation profile of tumor specimen MP2PRT-PAPPNT-TMP1-A (aliquot MP2PRT-PAPPNT-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPPNT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,801 days).
Specimen MP2PRT-PAPPNT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dcb512e-0959-4966-aa33-219b46fb51c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPPNT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPPNT-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b18ac165-9057-48fd-88cc-cb6293a0797e

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 13, Silent 8, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPZA3 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 26/392 reads (7%) | catalogued as rs15547; called by muse, mutect2
- CTCFL | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54780092; called by muse, mutect2
- DEAF1 | c.71_100del p.A24_A33del | In Frame Del (DEL) | VAF 415/647 reads (64%) | catalogued as rs761172741; called by mutect2, pindel, varscan2
- GABRA1 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99195757; called by muse, mutect2
- GRIA3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 128/159 reads (81%) | catalogued as rs183018401; called by muse, mutect2, varscan2
- MMRN2 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 152/611 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.089); catalogued as rs778073215; called by muse, mutect2, varscan2
- SIGMAR1 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 114/473 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs149409262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC27 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as rs759730569; called by muse, mutect2, varscan2
- COX15 | c.1132T>G p.Y378D | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DPH2 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- HDAC2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1D-8 | chr2:90221382 TCCCACAGTGTTAC>CACGG | Missense Mutation (DEL) | VAF 31/60 reads (52%) | called by pindel, varscan2*
- ITGA1 | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); called by muse, mutect2
- JPH2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 255/637 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- REV3L | c.6655C>G p.L2219V | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SETD3 | c.969_970insTTCCCCCGCT p.H324Ffs*10 | Frame Shift Ins (INS) | VAF 66/248 reads (27%) | called by mutect2, pindel, varscan2
- TRBJ2-5 | c.1_5del p.Q2Dfs*? | Frame Shift Del (DEL) | VAF 98/347 reads (28%) | called by pindel*, varscan2
- ZNF419 | c.1225A>G p.R409G | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ANK3 | c.13107G>A p.R4369= (on ENST00000280772 / NM_001320874.2; = p.R993= on NM_001149.3) | Silent (SNP) | VAF 34/306 reads (11%) | catalogued as rs779411401; called by muse, mutect2
- C20orf85 | c.405C>T p.G135= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as rs140824842, COSV100959375; called by muse, mutect2, varscan2
- CACNA1A | c.12C>T p.F4= | Silent (SNP) | VAF 28/560 reads (5%) | called by muse, mutect2
- MUC6 | c.693C>A p.I231= | Silent (SNP) | VAF 18/532 reads (3%) | called by muse, mutect2
- SLCO2A1 | c.616C>T p.L206= | Silent (SNP) | VAF 22/337 reads (7%) | called by muse, mutect2
- TRUB1 | c.909T>C p.S303= | Silent (SNP) | VAF 150/358 reads (42%) | called by muse, mutect2, varscan2
- UFD1 | c.69C>T p.Y23= | Silent (SNP) | VAF 96/267 reads (36%) | catalogued as rs140263268; called by muse, mutect2, varscan2
- WASHC1 | c.841C>T p.L281= | Silent (SNP) | VAF 30/162 reads (19%) | catalogued as rs1210666967; called by muse, varscan2
